Gene-level copy-number profile of tumor specimen TCGA-OR-A5JY-01A from TCGA case TCGA-OR-A5JY, project TCGA-ACC (Adrenocortical Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adrenal cortical carcinoma; Tissue or organ of origin: Cortex of adrenal gland; Age at diagnosis: 69.0 years (25,190 days).
Specimen TCGA-OR-A5JY-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-ACC.b8e37eaf-3103-4ff1-880b-fdd0923c2537.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-OR-A5JY-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 828 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/0997d0d2-d4a8-44ee-82a7-7a08e7a447dc

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 68; copy number 1: 240; copy number 2: 4,886; copy number 3: 17,304; copy number 4: 23,432; copy number 5: 4,395; copy number 6: 3,226; copy number 7: 2,760; copy number 8: 513; copy number 9: 1,549; copy number 10: 251; copy number 11: 963; copy number 12: 118; copy number 15: 1; copy number 18: 76; copy number 19: 13.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-OR-A5JY-01A-31D-A29H-01): tumor purity 0.84, ploidy 4.05, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 65 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:170,141,292–170,142,532, 1 gene: AC069306.1.
- chr4:181,522,666–181,591,969, 2 genes: AC093840.1, AC093840.2.
- chr8:1,246,789–2,926,689, 34 genes: AC110288.1, AF067845.2, AF067845.1, AF067845.5, AF067845.4, DLGAP2-AS1, AC100810.6, AC100810.2, CLN8, AC100810.3, AC100810.1, AC019257.8, MIR3674, AC100810.7, MIR596, ARHGEF10, AC019257.9, AC019257.1, KBTBD11-OT1, KBTBD11, AC019257.2, AC245164.1, MYOM2, MIR7160, AC245164.2, AC245519.1, AC245519.2, AC245187.2, AC245187.1, AC245123.1, AC246817.2, AC246817.1, AC115485.1, AC023296.1.
- chr8:3,373,353–3,426,587, 2 genes: AC026991.1, AC026991.2.
- chr13:19,552,571–19,588,603, 4 genes: MRPS31P2, ESRRAP1, LINC00350, CASC4P1.
- chr18:7,566,782–8,919,414, 22 genes (within-gene range 0–2): PTPRM, AP000897.2, AP000897.1, U3, AP005900.1, AC006566.2, AC006566.1, AP001094.3, AP001094.2, AP001094.1, COP1P1, RN7SL50P, THEMIS3P, AKR1B1P6, RAB12, AP001793.1, TOMM20P3, GACAT2, MTCL1, Y_RNA, AP000864.1, AP001531.1.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 2,955 genes in 34 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:69,995,966–74,589,481, 78 genes, copy number 9 (broad region; genes not listed).
- chr4:76,949,751–77,433,388, 9 genes, copy number 10 (within-gene range 6–10): SEPTIN11, TXNP6, CCNI, RPL7P17, AC104771.1, RNU6-1187P, CCNG2, AC008638.3, AC008638.2.
- chr4:77,862,830–77,952,785, 1 gene, copy number 9 (within-gene range 6–9): MRPL1.
- chr4:77,958,000–78,916,372, 17 genes, copy number 9 (within-gene range 4–9): AC114801.2, HMGB1P44, HNRNPA1P56, AC114801.1, AC114801.3, FRAS1, SERBP1P5, MICOS10P4, ANXA3, Y_RNA, LINC01094, HIGD1AP13, AC112253.1, AC098818.1, AC098818.2, BMP2K, AC098818.3.
- chr4:86,594,315–87,894,015, 31 genes, copy number 9 (within-gene range 5–9): PTPN13, SLC10A6, AC093827.1, C4orf36, AC093827.2, AC093827.5, AC093827.3, AC093827.4, AFF1, TECRP1, KLHL8, AC092658.1, GAPDHP60, AC108516.1, MIR5705, HSD17B13, AC108516.2, HSD17B11, RN7SL681P, AC112250.1, NUDT9, AC112250.2, SPARCL1, AC093895.1, DSPP, DMP1, Y_RNA, CHCHD2P7, IBSP, MEPE, HSP90AB3P.
- chr4:102,251,041–102,450,010, 3 genes, copy number 10 (within-gene range 3–10): SLC39A8, RN7SL728P, AC098487.1.
- chr4:108,788,745–109,879,897, 22 genes, copy number 10: RCC2P8, COL25A1, COL25A1-DT, RBMXP4, SEC24B-AS1, SEC24B, RN7SL55P, MIR576, SETP20, CDC42P4, MCUB, HIGD1AP14, CASP6, AC004067.1, PLA2G12A, AC126283.2, CFI, AC126283.1, GAR1, RRH, LRIT3, KRT19P3.
- chr4:114,598,770–115,113,876, 5 genes, copy number 19 (within-gene range 3–19): UGT8, MIR577, CIR1P2, RN7SL808P, NDST4.
- chr4:118,722,823–119,964,293, 23 genes, copy number 18: SEC24D, SYNPO2, AC096745.1, MYOZ2, AC092656.1, USP53, C4orf3, FABP2, KLHL2P1, RNU4-33P, AC110373.1, GTF2IP12, AC093752.3, RNU6-1217P, AC093752.1, AC093752.2, PDE5A, AC080089.1, AC080089.2, LINC01365, AC097173.1, LINC02502, Y_RNA.
- chr5:58,198–2,788,549, 84 genes, copy number 9 (broad region; genes not listed).
- chr5:4,451,930–4,866,311, 1 gene, copy number 9 (within-gene range 8–9): AC106799.2.
- chr5:4,640,731–17,276,843, 204 genes, copy number 9 (broad region; genes not listed).
- chr5:24,487,100–82,276,857, 869 genes, copy number 9 (within-gene range 8–9) (broad region; genes not listed).
- chr6:72,316,599–73,198,853, 7 genes, copy number 9 (within-gene range 6–9): AL035633.1, FO393414.2, FO393414.1, FO393414.3, KCNQ5, MIR4282, KNOP1P4.
- chr7:9,869,774–21,221,428, 123 genes, copy number 9–10 (broad region; genes not listed).
- chr7:21,900,899–22,833,430, 13 genes, copy number 10: CDCA7L, RAPGEF5, RNA5SP227, STEAP1B, EEF1A1P6, AC002480.1, AC002480.2, IL6-AS1, IL6, MTCYBP42, AC073072.1, TOMM7, AC005682.2.
- chr8:119,325,171–119,673,453, 8 genes, copy number 19 (within-gene range 4–19): MIR548AZ, AC021733.4, AC021733.1, CCN3, AC021733.2, AC021733.3, ENPP2, CYCSP23.
- chr8:121,612,116–124,120,061, 52 genes, copy number 18 (within-gene range 4–18): HAS2, HAS2-AS1, LINC02855, AC037486.1, MRPS36P3, SMILR, LINC01151, AC108136.1, AC100872.1, AC100872.2, CDK5P1, AC016405.3, AC016405.2, ZHX2, AC016405.1, AC104316.2, AC104316.1, DERL1, TBC1D31, HMGB1P19, AC068228.3, FAM83A, U3, AC068228.1, AC068228.2, FAM83A-AS1, MIR4663, C8orf76, ZHX1-C8orf76, UBA52P5, ZHX1, RNU6-628P, AC018992.1, ATAD2, RNU6-875P, MIR548AA1, MIR548D1, DUTP2, IMPDH1P6, NTAQ1, U4, FBXO32, AC090193.1, RN7SKP155, AC135166.1, KLHL38, ANXA13, FAM91A1, FER1L6, AC090753.1, FER1L6-AS1, AC100871.2.
- chr12:4,247,981–5,092,742, 30 genes, copy number 9: CCND2-AS1, CCND2, AC008012.1, TIGAR, AC006122.1, FGF23, FGF6, C12orf4, RAD51AP1, DYRK4, AC005832.2, AC005832.4, AKAP3, AC005832.3, AC005832.1, NDUFA9, AC005833.1, GAU1, GALNT8, AC005833.2, KCNA6, AC006063.1, AC006063.3, AC006063.4, AC005906.2, KCNA1, AC006063.2, AC005906.1, KCNA5, AC005906.3.
- chr12:20,368,537–21,419,594, 12 genes, copy number 9 (within-gene range 4–9): PDE3A, UBE2L2, AC112777.1, SLCO1C1, SLCO1B3, SLCO1B3-SLCO1B7, AC011604.1, SLCO1B7, AC022335.1, SLCO1B1, SLCO1A2, IAPP.
- chr12:25,779,287–26,421,462, 18 genes, copy number 11: RN7SKP262, AC019209.3, TDGP1, AC019209.2, MIR4302, AC019209.1, RASSF8-AS1, RASSF8, BHLHE41, SSPN, AC022509.3, AC022509.5, AC022509.2, AC022509.1, AC022509.4, AC055720.1, AC055720.3, AC024145.1.
- chr12:26,335,864–26,373,733, 2 genes, copy number 11: AC055720.2, RNA5SP354.
- chr12:33,717,853–72,186,618, 979 genes, copy number 11–12 (broad region; genes not listed).
- chr12:72,249,964–72,276,954, 1 gene, copy number 11: TRHDE-AS1.
- chr12:73,115,957–73,143,858, 1 gene, copy number 15: AC090503.2.
- chr12:79,341,205–80,068,757, 15 genes, copy number 11–12: AC027288.3, MIR1252, AC027288.2, AC027288.1, NOP56P3, PAWR, AC073569.2, PPP1R12A, AC073569.3, AC073569.1, RNA5SP363, PPP1R12A-AS1, SNRPGP20, RPL7P38, RNU7-106P.
- chr12:80,102,899–80,103,333, 1 gene, copy number 12: AC078817.1.
- chr12:120,095,099–120,463,749, 24 genes, copy number 11 (within-gene range 6–11): RAB35, AC004812.2, GCN1, MIR4498, RPLP0, PXN-AS1, PXN, AC004263.2, AC004263.1, RPS20P31, NME2P1, RNU4-2, RNU4-1, SIRT4, RNU6-1088P, PLA2G1B, MSI1, RPS27P25, AC003982.1, COX6A1, AL021546.1, TRIAP1, GATC, RPL31P52.
- chr15:19,878,555–22,617,854, 139 genes, copy number 10 (broad region; genes not listed).
- chr15:25,580,969–25,581,122, 1 gene, copy number 18: AC023449.1.
- chr15:36,579,626–37,254,952, 15 genes, copy number 11 (within-gene range 7–11): CDIN1, AC103988.1, LARP4P, TPST2P1, AC013640.1, CSNK1A1P1, U3, AC018563.1, MEIS2, MIR8063, Y_RNA, AC078909.1, AC078909.2, Metazoa_SRP, AC087283.1.
- chr15:56,542,952–62,844,631, 139 genes, copy number 9–12 (within-gene range 6–12) (broad region; genes not listed).
- chr15:69,278,328–70,602,516, 24 genes, copy number 9: AC026992.2, AC026992.1, PAQR5, AC027237.4, AC027237.3, Y_RNA, KIF23, AC027237.1, RPLP1, U3, AC027237.2, DRAIC, AC100826.1, GEMIN8P1, AC021818.1, TLE3, MIR629, RNU6-745P, AC026583.1, AC048383.1, LINC02205, AC009434.1, LINC02204, AC087699.1.
- chr22:19,875,517–19,969,975, 4 genes, copy number 9 (within-gene range 5–9): TXNRD2, AC000078.1, COMT, MIR4761.

Autosomal genes at a single copy (total copy number 1): 240. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
